HCMI case HCM-CSHL-0371-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/69b4a2cd-dc6f-4413-bdb4-b6f44ff8677f

Demographics
Sex at birth: female; Year of birth: 1943; Vital status: Dead; Days to death: 344 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.2; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Tail of pancreas; Classification of tumor: primary; Age at diagnosis: 75.0 years (27,380 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 11.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -6 days.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (2 entries)
- Days to follow up: 344 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 235.

Molecular and laboratory tests
- CA19-9: 248.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Intraductal Papillary Mucinous Neoplasm; Comorbidity method of diagnosis: Radiology.
- Timepoint category: Initial Diagnosis; Weight: 54 kg; Height: 160 cm; BMI: 21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0371-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0371-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 9.
  Slide HCM-CSHL-0371-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 9; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 10.
- Sample HCM-CSHL-0371-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0371-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
